CPTAC case C3N-01714 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fa3bda9a-329f-4422-9c13-10c38f546862

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Dead; Days to death: 435 days (1.2 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 63.4 years (23,163 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 435 days (1.2 years); Progression or recurrence: yes; Days to last follow up: 448 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 2.7 cm); Lymph node involvement: Positive; Lymph nodes positive: 16; Lymph nodes tested: 36; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 448 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 386 days (1.1 years); Karnofsky performance status: 0.

Other clinical attributes
- Weight: 70 kg; Height: 168 cm; BMI: 24.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01714-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 143 mg.
- Sample C3N-01714-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 318 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01714-22: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 2.
- Sample C3N-01714-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
